Somatic mutation profile of tumor specimen 0DWES7 from CCDI case PBCNRT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Nasopharynx, NOS; Age at diagnosis: 16.7 years (6,112 days).
Specimen 0DWES7: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc948d8d-6fa4-4a01-a3fe-6d0795222a53.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWERY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9de496e5-22b5-4025-bb56-e12cd8f2fc95

The open-access MAF lists 53 somatic variants for this specimen: 33 protein-altering or splice-affecting, 13 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 13, Intron 4, 5'UTR 2, Nonsense Mutation 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPHA3 | c.406C>T p.R136* | Nonsense Mutation (SNP) | VAF 26/506 reads (5%) | hotspot (GDC flag); catalogued as rs770780950, COSV60693907; called by muse, mutect2
- CNGA3 | c.2053G>A p.D685N | Missense Mutation (SNP) | VAF 40/820 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as rs1357724875; called by muse, mutect2
- CSMD2 | c.2915A>G p.E972G | Missense Mutation (SNP) | VAF 99/424 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763522005; called by muse, mutect2, varscan2
- GIMD1 | c.584G>C p.R195T | Missense Mutation (SNP) | VAF 22/398 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs750917441; called by muse, mutect2
- GIPC3 | c.929G>A p.R310Q (on ENST00000644946; = p.E306K on NM_133261.3) | Missense Mutation (SNP) | VAF 91/563 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.86); catalogued as rs772055400; called by muse, mutect2, varscan2
- HMCN2 | c.12524C>T p.T4175M | Missense Mutation (SNP) | VAF 28/508 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.51); catalogued as rs960747751; called by muse, mutect2
- IFT46 | c.763C>T p.R255W (on ENST00000264021 / NM_001168618.2; = p.R306W on NM_020153.3) | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as rs782137705; called by muse, mutect2
- MTARC2 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 55/461 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.116); catalogued as rs372859442; called by muse, mutect2, varscan2
- PXK | c.1619C>T p.S540L | Missense Mutation (SNP) | VAF 33/628 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs773826594; called by muse, mutect2
- SLC12A4 | c.2560G>A p.D854N | Missense Mutation (SNP) | VAF 40/622 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs369106532; called by muse, mutect2
- TGFBR2 | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 25/503 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs1431838247; called by muse, mutect2
- UNC5D | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 15/452 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54783277; called by muse, mutect2
- AATK | c.3665G>A p.C1222Y (on ENST00000326724 / NM_001080395.3; = p.C1119Y on NM_004920.2) | Missense Mutation (SNP) | VAF 70/551 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- ADAM32 | c.1706T>G p.V569G | Missense Mutation (SNP) | VAF 25/378 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- AJM1 | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 48/585 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.23); called by muse, mutect2
- C10orf95 | c.607C>A p.R203S | Missense Mutation (SNP) | VAF 84/422 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- COL12A1 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 26/404 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); called by muse, mutect2
- CYP7B1 | c.1426G>C p.D476H | Missense Mutation (SNP) | VAF 41/490 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2
- FAM189A1 | c.410T>A p.V137E | Missense Mutation (SNP) | VAF 69/590 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- JPH3 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 29/661 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- LCT | c.3032A>T p.N1011I | Missense Mutation (SNP) | VAF 34/363 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- OR5D14 | c.37A>T p.T13S | Missense Mutation (SNP) | VAF 32/571 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by muse, mutect2
- PCDHGB3 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 30/440 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- PI4KB | c.2017C>T p.H673Y (on ENST00000368873 / NM_001369623.1; = p.H685Y on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/260 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP2R3B | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 18/402 reads (4%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2
- PXMP2 | c.375C>A p.F125L | Missense Mutation (SNP) | VAF 22/498 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- SLAIN1 | c.1363C>T p.Q455* (on ENST00000466548; = p.Q192* on NM_144595.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 17/196 reads (9%) | called by muse, mutect2
- SLC2A13 | c.653G>A p.G218E | Missense Mutation (SNP) | VAF 20/540 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); called by muse, mutect2
- SMO | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 40/256 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- TDRD6 | c.5254G>A p.E1752K | Missense Mutation (SNP) | VAF 34/389 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.196); called by muse, mutect2
- USP19 | c.3902T>A p.V1301E | Missense Mutation (SNP) | VAF 32/616 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.203); called by muse, mutect2
- YTHDF3 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 48/462 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.05); called by muse, mutect2
- ZWINT | c.205C>G p.Q69E | Missense Mutation (SNP) | VAF 30/602 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.156); called by muse, mutect2
- CEP250 | c.2346G>A p.V782= | Silent (SNP) | VAF 73/630 reads (12%) | called by muse, mutect2, varscan2
- CRISP2 | c.180G>A p.K60= | Silent (SNP) | VAF 19/311 reads (6%) | called by muse, mutect2
- CYP2U1 | c.1533C>T p.F511= | Silent (SNP) | VAF 37/371 reads (10%) | catalogued as rs372600671; called by muse, mutect2, varscan2
- EPHB2 | c.2097C>T p.T699= (on ENST00000400191 / NM_001309193.2; = p.T700= on NM_004442.7) | Silent (SNP) | VAF 58/582 reads (10%) | catalogued as rs538962894, COSV65861402; called by muse, mutect2, varscan2
- HES7 | c.336G>A p.P112= | Silent (SNP) | VAF 28/384 reads (7%) | called by muse, mutect2
- IL17C | c.132C>T p.L44= | Silent (SNP) | VAF 29/380 reads (8%) | catalogued as rs906742659, COSV54918499; called by muse, mutect2
- LRCH4 | c.1284G>A p.P428= | Silent (SNP) | VAF 37/493 reads (8%) | catalogued as rs763750913, COSV59642588; called by muse, mutect2
- MRC1 | c.129C>T p.A43= | Silent (SNP) | VAF 67/394 reads (17%) | catalogued as rs781852223; called by muse, mutect2, varscan2
- OCSTAMP | c.522G>A p.L174= | Silent (SNP) | VAF 14/398 reads (4%) | called by muse, mutect2
- SLC35F2 | c.234C>T p.I78= | Silent (SNP) | VAF 35/360 reads (10%) | called by muse, mutect2, varscan2
- TNFRSF1A | c.1140G>A p.L380= | Silent (SNP) | VAF 42/693 reads (6%) | catalogued as rs369290223; called by muse, mutect2
- TRIM58 | c.132C>T p.C44= | Silent (SNP) | VAF 50/327 reads (15%) | called by muse, mutect2, varscan2
- ZNF786 | c.540C>T p.P180= | Silent (SNP) | VAF 62/478 reads (13%) | catalogued as rs374128975; called by muse, mutect2, varscan2
- AKT2 | c.573+51G>A | Intron (SNP) | VAF 15/134 reads (11%) | called by muse, mutect2, varscan2
- ELN | c.377-37G>A | Intron (SNP) | VAF 32/605 reads (5%) | called by muse, mutect2
- IL18 | c.91+53C>T | Intron (SNP) | VAF 8/160 reads (5%) | called by muse, mutect2
- INTS6 | c.112-50C>T | Intron (SNP) | VAF 12/105 reads (11%) | catalogued as rs1247063597; called by muse, mutect2, varscan2
- PEDS1 | c.-71C>T | 5'UTR (SNP) | VAF 16/159 reads (10%) | called by muse, mutect2, varscan2
- PIP5K1A | c.-21G>A | 5'UTR (SNP) | VAF 29/224 reads (13%) | called by muse, mutect2, varscan2
- PPBP | c.*13C>T | 3'UTR (SNP) | VAF 12/310 reads (4%) | called by muse, mutect2
